Somatic mutation profile of tumor specimen MP2PRT-PAVMMM-TMP1-A (aliquot MP2PRT-PAVMMM-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVMMM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.7 years (2,430 days).
Specimen MP2PRT-PAVMMM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7057f54-0dbe-4fac-a472-14373fca8339.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVMMM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVMMM-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7276e2cb-0805-4d7d-a14e-4513ab8cf6d7

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Splice Region 1, Nonsense Mutation 1, Frame Shift Del 1, In Frame Del 1, 3'Flank 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM149A | c.1675C>T p.R559W (on ENST00000356371 / NM_001367768.2; = p.R268W on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/271 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as rs779900401; called by muse, mutect2, varscan2
- ITGAL | c.2620-1G>C p.X874_splice | Splice Site (SNP) | VAF 78/244 reads (32%) | catalogued as COSV63323628; called by muse, mutect2, varscan2
- KIAA1217 | c.4681G>A p.A1561T | Missense Mutation (SNP) | VAF 142/479 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs764141082; called by muse, mutect2
- KIF19 | c.274G>C p.V92L | Missense Mutation (SNP) | VAF 143/452 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.397); catalogued as COSV63429800; called by muse, mutect2, varscan2
- LACTBL1 | c.389+5G>A | Splice Region (SNP) | VAF 179/554 reads (32%) | catalogued as rs1249868717; called by muse, mutect2, varscan2
- LONRF2 | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 109/378 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); catalogued as rs746801961; called by muse, mutect2, varscan2
- MYO15A | c.5899C>T p.R1967C | Missense Mutation (SNP) | VAF 71/269 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs758544158; called by muse, mutect2, varscan2
- PRKCI | c.1213C>T p.R405W | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs763152419, COSV55517129; called by muse, mutect2, varscan2
- SDCCAG8 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 162/562 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.809); catalogued as rs769004589, COSV59416613; called by muse, mutect2, varscan2
- EPHB4 | c.2412G>A p.W804* | Nonsense Mutation (SNP) | VAF 121/418 reads (29%) | called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406870 ATTCACAGTG>C | Missense Mutation (DEL) | VAF 32/102 reads (31%) | called by pindel, varscan2*
- IGSF9B | c.3958C>T p.P1320S | Missense Mutation (SNP) | VAF 72/433 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAJ23 | c.4_6del p.I2_Y3delinsN | In Frame Del (DEL) | VAF 35/161 reads (22%) | called by pindel*, varscan2
- ZMYM2 | c.1721_1722del p.Y574Cfs*14 | Frame Shift Del (DEL) | VAF 29/172 reads (17%) | called by pindel, varscan2
- MPDZ | c.4545G>T p.G1515= | Silent (SNP) | VAF 123/395 reads (31%) | catalogued as COSV59924641; called by muse, mutect2, varscan2
- PAK5 | c.1548C>T p.G516= | Silent (SNP) | VAF 109/408 reads (27%) | called by muse, varscan2
- TASP1 | c.174C>T p.A58= | Silent (SNP) | VAF 54/248 reads (22%) | called by muse, mutect2
- UNC5D | c.1833C>T p.I611= | Silent (SNP) | VAF 108/357 reads (30%) | catalogued as rs369520847, COSV54811377; called by muse, mutect2, varscan2
- IGHV3-53 | chr14:106592675 ins AATTGA | 3'Flank (INS) | VAF 34/84 reads (40%) | called by mutect2, pindel, varscan2
- PLPPR2 | c.*261C>T | 3'UTR (SNP) | VAF 20/698 reads (3%) | catalogued as COSV52261616; called by muse, mutect2
